Somatic mutation profile of tumor specimen TCGA-C5-A7CG-01A (aliquot TCGA-C5-A7CG-01A-11D-A32I-09) from TCGA case TCGA-C5-A7CG, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 55.4 years (20,242 days).
Specimen TCGA-C5-A7CG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79cd809e-0b6f-4be1-afcd-aba86fa373ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A7CG-10A (Blood Derived Normal), aliquot TCGA-C5-A7CG-10A-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8c12c74-c4c9-43b9-af78-0de165f8716a

The open-access MAF lists 56 somatic variants for this specimen: 45 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 10, Frame Shift Del 6, Splice Site 3, Nonsense Mutation 3, Frame Shift Ins 1, 3'Flank 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4195G>A p.D1399N | Missense Mutation (SNP) | VAF 25/40 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519889, COSV54325045, COSV54326888, COSV54344606; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.670C>T p.R224* (on ENST00000281708 / NM_001349798.2; = p.R144* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 19/66 reads (29%) | hotspot (GDC flag); catalogued as rs1406877044, COSV55899023; called by muse, mutect2, varscan2
- BIRC6 | c.11163C>G p.H3721Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.34); catalogued as rs1219575136; called by muse, mutect2, varscan2
- CASP5 | c.1096+1G>A p.X366_splice | Splice Site (SNP) | VAF 7/51 reads (14%) | catalogued as rs141481245; called by muse, mutect2, varscan2
- CFHR5 | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.147); catalogued as rs776063846, COSV56821819, COSV56827323; ClinVar: likely benign; called by muse, mutect2, varscan2
- DISP2 | c.2827C>T p.R943C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs1156805822; called by muse, mutect2, varscan2
- DSCAM | c.4849C>T p.R1617W | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as rs772464092, COSV68021092, COSV68028546; called by muse, mutect2, varscan2
- FGF14 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.684); catalogued as rs757879324, COSV65935613; called by muse, mutect2
- FMNL1 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs146945062; called by muse, mutect2, varscan2
- FNDC1 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs780310956; called by muse, mutect2, varscan2
- GRM1 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV51117094; called by muse, mutect2, varscan2
- KCNA6 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as rs1379142356, COSV54973795; called by muse, mutect2, varscan2
- KCNT1 | c.1036C>T p.R346C (on ENST00000488444; = p.R365C on NM_020822.3) | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs751116785, COSV53708577; called by muse, mutect2, varscan2
- KIFC2 | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs368447948; called by muse, mutect2, varscan2
- NBEAL2 | c.1855A>G p.T619A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV52763481; called by mutect2, varscan2
- NUP155 | c.2798C>G p.S933C (on ENST00000231498 / NM_153485.3; = p.S874C on NM_004298.4) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs766476048; called by muse, mutect2, varscan2
- OR10H3 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.955); catalogued as COSV100008544; called by muse, mutect2
- SDK2 | c.4619G>A p.R1540Q | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as rs771273833, COSV66188291; called by muse, mutect2, varscan2
- SLC47A1 | c.691_693del p.L231del | In Frame Del (DEL) | VAF 14/49 reads (29%) | catalogued as rs1177155761; called by pindel, varscan2
- SPA17 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs925623136, COSV57033352; called by muse, mutect2, varscan2
- SYT6 | c.1397G>A p.R466H (on ENST00000610222 / NM_001366225.1; = p.R381H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as rs148168972, COSV65775747; called by muse, mutect2, varscan2
- TNIK | c.1046C>T p.T349M | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs899660528, COSV99460066; called by muse, mutect2
- UHRF2 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 10/101 reads (10%) | catalogued as COSV99436373; called by muse, mutect2
- ZBTB16 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs1375735901; called by muse, mutect2
- ARHGEF6 | c.1560T>C p.G520= | Splice Region (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- BEND3 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- CEP162 | c.1955A>T p.E652V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- FAM50B | c.596_612del p.R199Qfs*69 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- FAT1 | c.4279del p.L1427Sfs*20 | Frame Shift Del (DEL) | VAF 23/70 reads (33%) | called by mutect2, pindel, varscan2
- GNS | c.1574_1580del p.P526Tfs*52 | Frame Shift Del (DEL) | VAF 8/103 reads (8%) | called by mutect2, pindel
- ITCH | c.1184_1185del p.R395Qfs*3 (on ENST00000262650 / NM_001257137.3; = p.R354Qfs*3 on NM_031483.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 23/92 reads (25%) | called by mutect2, pindel, varscan2
- MAP1B | c.3935G>T p.S1312I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYH1 | c.5374C>A p.Q1792K | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- NAALAD2 | c.890+2T>C p.X297_splice | Splice Site (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- SLC44A1 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 48/84 reads (57%) | SIFT tolerated (0.32); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SNAP91 | c.2197G>A p.G733R | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TGFB2 | c.161dup p.E55Rfs*5 | Frame Shift Ins (INS) | VAF 22/78 reads (28%) | called by mutect2, pindel, varscan2
- TTC17 | c.650_659del p.E217Gfs*26 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- UBE3A | c.1475G>T p.G492V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- UBR4 | c.13613_13626+1del p.X4538_splice | Splice Site (DEL) | VAF 14/55 reads (25%) | called by mutect2, pindel, varscan2
- VPS35L | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- YWHAE | c.496A>G p.T166A | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZCWPW1 | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ZNF100 | c.453_456del p.S151Rfs*14 | Frame Shift Del (DEL) | VAF 16/71 reads (23%) | called by mutect2, pindel, varscan2
- ZNF23 | c.908C>T p.T303I | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- AF196969.1 | c.162G>A p.A54= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs1205158635, COSV52142140; called by muse, mutect2, varscan2
- FAM193A | c.30G>A p.S10= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs777305061, COSV100219660; called by muse, mutect2, varscan2
- GJD4 | c.807C>T p.R269= | Silent (SNP) | VAF 17/85 reads (20%) | called by muse, mutect2, varscan2
- GRID1 | c.1821C>T p.S607= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs200091837, COSV60023458; called by mutect2, varscan2
- LRP1B | c.4239G>A p.G1413= | Silent (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- NUP210L | c.3612C>A p.S1204= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV99668766; called by muse, mutect2
- OPHN1 | c.2337G>A p.R779= | Silent (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2, varscan2
- PIM1 | c.333G>A p.E111= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs1262639037; called by muse, mutect2, varscan2
- PPARD | c.1257G>T p.R419= | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- ZDHHC12 | c.447G>A p.Q149= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, varscan2
- COPS9 | chr2:240126583 G>T | 3'Flank (SNP) | VAF 3/31 reads (10%) | catalogued as COSV56229191; called by muse, mutect2
